Surgical pathology report (de-identified scan), TCGA case TCGA-85-A4CN, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A4CN-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Lobe with the bronchus obstructed by a tumoral structure with a diameter of 6/7/6 cm; the tumor spreads to periphery without invading the pleura.

Microscopic Description: TUMOR FRAGMENT:

Bronchopulmonary neoplasm of epidermoid carcinoma type, with keratinization, G2, formed of solid beaches of relatively pleomorphic cells with intralobular keratotic globes; fibrous-inflammatory stromal reaction.

INTERLOBAR LYMPH NODE:

Lymph node with neoplastic infiltrates of the epidermoid carcinoma.

HILAR LYMPH NODE: with tumoral infiltrates.

TRIANGULAR LIGAMENT LYMPH NODE:

3 lymph nodes; no metastases.

SUBAORTIC LYMPH NODE: No metastases.

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 6 x 7 x 6 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 2/6 positive for metastasis (Regional 2/6)

Lymphatic invasion: Not specified

Venous invasion: Not specified

ICD - 0 - 3

carcinoma, squamous cell, NOS
8070/3

Site: lung, lower ^(L) lobe C 34.3

ju
9/26/12

[page 2 of 2]
Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- lower

9/3/12

Source: NCI Genomic Data Commons file 63b78ead-5815-464a-a8ec-af56bae1e27a (TCGA-85-A4CN.EE8604DB-464B-4B27-BD77-1CA923637F2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).